Surgical pathology report (de-identified scan), TCGA case TCGA-AX-A2IN, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-AX-A2IN-01A (Primary Tumor).

[page 1 of 6]
Diagnostic Discrepancy		✓
HPOA Discrepancy		✓
Dual/Synchronous Primary Site(s)		✓

RUN DATE:
RUN TIME
BY:

PATIENT:

ACCT #:

LOC:

U#:

REG DR:

MD

AGE/SX:

1/F

RM/BED:

REG:

STATUS:

TLOC:

DIS:

SPEC #:

Obtained:

Subm Dr:

STATUS:

Received:

CLINICAL HISTORY:

ENDOMETRIAL CANCER

1CB-0-3

*adenocarcinoma, endometrioid, NOS
8380/3*

SPECIMEN/PROCEDURE:

Site: endometrium c54.1

1. UTERUS - WITH TUBES & OVARIES; TAH/BSO/NODE DISSECTION
2. LYMPH NODE - RIGHT PARA AORTIC
3. LYMPH NODE - RIGHT PELVIC
4. LYMPH NODE - LEFT PARA AORTIC
5. LYMPH NODE - LEFT PELVIC
6. LYMPH NODE - LEFT COMMON ILIAC
7. OMENTUM
8. LYMPH NODE - RIGHT COMMON ILIAC

hw 7/24/11

IMPRESSION:

- 1) UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES, TOTAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY:
- ENDOMETRIUM:
- Endometrial adenocarcinoma, endometrioid type, FIGO grade III nuclear grade 2.
- Non-carcinoma involved endometrium, cystic atrophy.
- MYOMETRIUM:
- Myometrial invasion, more than 50% (8.5 mm of 10 mm, 85%).
- Lymphovascular space invasion, present.
- Leiomyoma.
- Adenomyosis.
- CERVIX:
- Carcinoma involvement, absent.
- UTERINE SEROSA:
- Negative for endometrial adenocarcinoma.
- BILATERAL OVARIES:
- Atrophic, negative for endometrial adenocarcinoma.
- BILATERAL FALLOPIAN TUBES:
- Negative for endometrial adenocarcinoma.
- 2) LYMPH NODE, RIGHT PARA-AORTIC, BIOPSY:
- One lymph node, negative for endometrial adenocarcinoma (0/1).
- 3) LYMPH NODES, RIGHT PELVIC, DISSECTION:

** CONTINUED ON NEXT PAGE **

[page 2 of 6]
IMPRESSION: (continued)

- Seven lymph nodes, negative for endometrial adenocarcinoma (0/7).
- 4) Lymph nodes, left para-aortic, dissection:
Three lymph nodes, negative for endometrial adenocarcinoma (0/3).
- 5) Lymph nodes, left pelvic, dissection:
Ten lymph nodes, negative for endometrial adenocarcinoma (0/10).
- 6) Lymph node, left common iliac, biopsy:
One lymph node, negative for endometrial adenocarcinoma (0/1).
- 7) Omentum, omentectomy:
Mature adipose tissue, negative for endometrial adenocarcinoma.
- 8) Lymph nodes, right common iliac, dissection:
Three lymph nodes, negative for endometrial adenocarcinoma (0/3).

ENDOMETRIAL CARCINOMA CHECKLIST**MACROSCOPIC****SPECIMEN TYPE**
Hysterectomy**TUMOR SITE**

Specify location: Anterior and posterior

TUMOR SIZE

Greatest dimension: 4.5 cm

Additional dimensions: 4.5 x 2.0 cm

OTHER ORGANS PRESENT

Right ovary

Left ovary

Right fallopian tube

Left fallopian tube

MICROSCOPIC**HISTOLOGIC TYPE**

Endometrioid adenocarcinoma, not otherwise characterized

HISTOLOGIC GRADE

G3: More than 50% nonsquamous solid growth

[page 3 of 6]
IMPRESSION: (continued)**MYOMETRIAL INVASION****Invasion present**

Maximal depth of myometrial invasion: 8.5 mm

Thickness of myometrium in area of maximal tumor invasion: 10 mm

The % of myometrial involvement: 85%

EXTENT OF INVASION**PRIMARY TUMOR (pT)**

pT1c (IC): Tumor invades one-half or more of the myometrium

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

Number examined: 25

DISTANT METASTASIS (pM)

pMX: Cannot be assessed

MARGINS

Uninvolved by invasive carcinoma

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L)

Present

Pathologic TNM (AJCC 6th Edition): pT1c (IC) N0 M0

Dictated

Entered:

GROSS DESCRIPTION:

- 1) Received fresh, labeled with the patient's name, number and "uterus, tubes and ovaries", is a total abdominal hysterectomy, bilateral salpingo-oophorectomy specimen consisting of uterus (10.0 x 4.0 x 4.5 cm), right ovary (2.8 x 1.4 x 0.5 cm), right fallopian tube (5.5 x 0.5), left ovary (2.5 x 1.5 x 0.8 cm), and left fallopian tube (4.5 x 0.4 cm). The uterus is opened and part of tumor and left fallopian tube (normal tissue) is submitted for research. On opening the uterus, the endometrial cavity is 5.0 cm x 3.0 cm, and there is a 4.5 x 4.5 x 2.0 cm, yellow-tan fleshy tumor involving the corpus of the uterus and fungating to involve the superior part of the endometrium. The tumor grossly involves more than 90% of the myometrium and almost extends to the serosal surface superiorly. The lower segment of the uterus, endocervical canal (3.2 cm in length), and cervix are grossly uninvolved by the tumor. There is a 5.0 x 4.0 x 3.5 cm, soft to firm, subserosal leiomyoma in the anterior lower segment of the uterus. The bilateral adnexa is grossly uninvolved by the tumor. Bilateral ovaries are covered with pink-tan to red serosal surface and on sectioning reveal pink, homogeneous parenchyma. The left fallopian tube is grossly unremarkable

** CONTINUED ON NEXT PAGE **

[page 4 of 6]
GROSS DESCRIPTION: (continued)

and the right fallopian tube has multiple small paratubal cysts ranging from 0.1 to 0.3 cm in maximum diameter. The specimen is representatively sectioned and submitted as follows:

CASSETTE SUMMARY:

Cassette 1A: Representative section of the left ovary and fallopian tube.
Cassette 1B: Representative section of the right ovary and fallopian tube.
Cassette 1C: Anterior cervix.
Cassette 1D: Posterior cervix.
Cassette 1E-1J: Full thickness section of the tumor (posterior uterine wall).
Cassette 1K-1N: Full thickness section of the tumor (anterior wall).
Cassette 1P-1R: Representative sections of the anterior lower uterine segment leiomyoma.

- 2) Received in formalin, labeled "right para-aortic lymph node" and with the patient's name, is an irregular portion of yellow-tan lobulated adipose tissue, 2.0 x 1.8 x 0.7 cm. The specimen is dissected for lymph nodes, there is one tan ovoid lymph node identified, 1.5 x 0.8 x 0.6 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 2: One lymph node, bivalved.

- 3) Received in formalin, labeled "right pelvic lymph nodes" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, 5.0 x 3.0 x 1.7 cm. The specimen is dissected for lymph nodes, there are seven tan ovoid lymph nodes identified, ranging from 1.0 x 0.6 x 0.3 cm to 1.8 x 0.8 x 0.5 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 3A: Three lymph nodes.
Cassette 3B: Two lymph nodes, bivalved, one inked blue.
Cassette 3C: Two lymph nodes, bivalved, one inked blue.

- 4) Received in formalin, labeled "left para-aortic lymph node" and with the patient's name, are three irregular portions of yellow-tan lobulated adipose tissue, ranging from 1.0 x 1.0 x 0.5 cm to 1.5 x 1.3 x 0.6 cm. The specimen is dissected for lymph nodes, there are three red-tan ovoid lymph nodes identified, ranging from 0.5 x 0.5 x 0.2 cm to 2.0 x 0.6 x 0.3 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 4: Three lymph nodes.

- 5) Received in formalin, labeled "left pelvic lymph nodes" and with the patient's name, is an aggregate of irregular portions of yellow-tan lobulated adipose tissue, 5.5 x 4.0 x 1.7 cm. The specimen is dissected for lymph nodes, there are ten tan ovoid lymph nodes identified, ranging from 0.6 x 0.5 x 0.3 cm to 1.3 x 1.3 x 0.9 cm. All

** CONTINUED ON NEXT PAGE **

[page 5 of 6]
GROSS DESCRIPTION: (continued)

lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 5A: Five lymph nodes.
Cassette 5B: Two lymph nodes, bivalved, one inked blue.
Cassette 5C: Two lymph nodes, bivalved, one inked blue.
Cassette 5D: One lymph node, bivalved.

- 6) Received in formalin, labeled "left common iliac lymph node" and with the patient's name, is one irregular unoriented portion of yellow-tan lobulated adipose tissue, 4.0 x 1.5 x 0.6 cm. The specimen is dissected for lymph nodes, there is one tan ovoid lymph node identified, 1.5 x 0.9 x 0.5 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 6: One lymph node, bivalved.

- 7) Received in formalin, labeled "omentum" and with the patient's name, is an irregular unoriented portion of yellow-tan lobulated adipose tissue, 14.0 x 8.0 x 1.6 cm. The specimen is serially sectioned at close intervals, the cut surface is yellow-tan and lobulated, there are no obvious masses or lesions identified. The specimen is representatively sampled and submitted in three cassettes.
- 8) Received in formalin, labeled "right common iliac lymph node" and with the patient's name, is one irregular portion of yellow-tan lobulated adipose tissue, 2.0 x 1.5 x 0.8 cm. The specimen is bisected for lymph nodes, there is one tan ovoid lymph node identified, 0.5 x 0.6 x 0.5 cm. All lymph nodes identified are submitted as follows:

CASSETTE SUMMARY:

Cassette 8: One lymph node, bivalved.

Dictated

Entered:

COPIES TO:

Undefined Provider

** CONTINUED ON NEXT PAGE **

[page 6 of 6]
SPEC #:

PATIENT:

Page: 6
Continued)

CPT Codes:

LYMPH NODE BIOPSY (M)

UTERUS W/VO ADNEXAE, TUMOR-

LYMPH NODE, REGIONAL RESECT,
OMENTUM -

ICD9 Codes:

182.0, 218.1, 617.0

Electronically Signed by: _____

** END OF REPORT **

Source: NCI Genomic Data Commons file 9822c804-1395-444b-bc1a-7e95818286c0 (TCGA-AX-A2IN.3C67A037-8A4C-4345-B842-43F1F0A6A53E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).